Gene-level copy-number profile of tumor specimen CDDP-ACQ7-TTP1-A from CDDP_EAGLE case CDDP-ACQ7, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 55 years.
Specimen CDDP-ACQ7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 27e68907-63d9-4e41-9610-1e9db6c9fad7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACQ7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,771 have no estimate.
https://portal.gdc.cancer.gov/files/ac077703-44fc-457e-80f6-c3a87b663c87

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 417; copy number 1: 17,360; copy number 2: 37,009; copy number 3: 2,729; copy number 4: 1,188; copy number 5: 91; copy number 6: 4; copy number 7: 31; copy number 8: 1; copy number 10: 8; copy number 13: 2; copy number 14: 2; copy number 19: 10.

Homozygous deletions (total copy number 0; autosomes only): 119 genes in 62 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,904,339–16,904,776, 1 gene (within-gene range 0–2): BX284668.6.
- chr1:55,329,288–56,070,513, 1 gene (within-gene range 0–1): AL603840.1.
- chr1:64,028,894–64,029,000, 1 gene (within-gene range 0–1): RNU6-809P.
- chr1:83,445,967–83,480,024, 1 gene: LINC01712.
- chr1:94,650,544–94,651,378, 1 gene (within-gene range 0–1): KATNBL1P2.
- chr1:111,317,600–111,324,075, 2 genes (within-gene range 0–1): AL356387.1, AL356387.2.
- chr2:90,100,236–90,122,564, 3 genes (within-gene range 0–1): IGKV1D-16, IGKV3D-15, IGKV2D-14.
- chr3:8,501,807–8,593,124, 2 genes (within-gene range 0–1): LMCD1, AC034187.1.
- chr4:49,502,145–49,562,149, 9 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24.
- chr5:1,456,480–1,551,710, 3 genes: LPCAT1, MIR6075, AC091849.2.
- chr6:81,764,024–81,764,503, 2 genes: SNORA70, AL078599.1.
- chr6:168,242,938–168,375,355, 5 genes: AL606970.3, CTAGE13P, DACT2, AL606970.1, AL138918.1.
- chr6:170,639,606–170,696,950, 3 genes: OR4F7P, WBP1LP8, AL731661.1.
- chr7:1,530,702–1,560,821, 2 genes: MAFK, TMEM184A.
- chr7:157,501,322–157,518,658, 2 genes: AC006372.1, AC006372.2.
- chr8:6,996,766–7,018,297, 3 genes: DEFA1B, DEFT1P2, DEFA3.
- chr9:134,903,232–134,943,207, 2 genes: FCN1, AL353611.1.
- chr12:107,374,747–107,374,827, 1 gene (within-gene range 0–1): AC009774.1.
- chr12:107,732,871–107,761,272, 2 genes: PRDM4, AC007622.2.
- chr12:108,562,582–108,598,320, 2 genes: ISCU, TMEM119.
- chr12:109,445,410–109,477,359, 2 genes (within-gene range 0–1): AC007570.1, KCTD10.
- chr12:114,238,970–114,241,770, 1 gene: LINC02459.
- chr12:114,929,757–114,929,935, 1 gene: AC009804.1.
- chr12:124,383,381–124,383,510, 1 gene (within-gene range 0–1): AC073916.1.
- chr12:124,725,524–124,725,934, 1 gene: AC073593.1.
- chr12:124,911,604–124,935,895, 3 genes: UBC, MIR5188, RPL22P19.
- chr12:125,065,434–125,151,394, 3 genes: AACS, AC122688.3, AC122688.2.
- chr12:127,372,243–127,372,669, 1 gene: AC048347.1.
- chr12:130,138,693–130,165,740, 4 genes: AC026336.3, FZD10-AS1, AC026336.5, FZD10.
- chr12:130,383,364–130,383,890, 1 gene: AC127071.3.
- chr12:130,419,535–130,430,661, 2 genes (within-gene range 0–1): AC063926.1, AC063926.3.
- chr12:131,235,511–131,237,523, 1 gene: AC126564.1.
- chr12:131,299,640–131,299,751, 1 gene: RNA5SP376.
- chr12:132,077,803–132,131,639, 5 genes (within-gene range 0–1): AC137590.1, AC137590.2, EP400P1, AC138466.5, AC138466.2.
- chr12:132,196,372–132,332,432, 8 genes (within-gene range 0–1): GALNT9, AC138466.4, AC148477.3, AC148477.2, AC148477.5, AC148477.4, AC148477.1, AC148477.7.
- chr12:132,360,734–132,363,348, 2 genes: AC148477.6, AC148477.9.
- chr17:17,422,681–17,496,395, 5 genes: AC073621.1, TSEN15P1, Y_RNA, MED9, RASD1.
- chr17:18,393,480–18,414,380, 2 genes: TBC1D3P4, LINC02076.
- chr17:21,442,805–21,451,525, 2 genes: AC068418.3, PDLIM1P2.
- chr19:1,248,553–1,274,880, 3 genes (within-gene range 0–1): MIDN, CIRBP, CIRBP-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 149 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,247,222–32,286,165, 3 genes, copy number 5: FAM167B, LCK, Metazoa_SRP.
- chr1:40,333,078–40,333,557, 1 gene, copy number 5: AL031985.2.
- chr1:155,586,644–155,602,197, 2 genes, copy number 5: DAP3P1, AL353807.1.
- chr6:15,102,946–15,113,221, 2 genes, copy number 5: AL050335.1, RN7SL332P.
- chr6:26,686,241–26,687,964, 1 gene, copy number 8: AL513548.1.
- chr6:30,282,349–30,286,054, 1 gene, copy number 5 (within-gene range 3–5): AL662795.2.
- chr6:31,140,727–31,180,731, 5 genes, copy number 5: POLR2LP1, CCHCR1, TCF19, POU5F1, PSORS1C3.
- chr6:32,549,940–32,560,022, 2 genes, copy number 5 (within-gene range 3–5): RNU1-61P, HLA-DRB6.
- chr6:32,706,124–32,731,695, 3 genes, copy number 5: MTCO3P1, AL662789.1, HLA-DQB3.
- chr6:33,540,046–33,589,026, 4 genes, copy number 5 (within-gene range 2–5): GGNBP1, RN7SL26P, Metazoa_SRP, BAK1.
- chr6:34,417,454–34,426,069, 1 gene, copy number 5 (within-gene range 4–5): RPS10.
- chr6:37,170,152–37,175,428, 1 gene, copy number 5: PIM1.
- chr6:42,727,234–42,868,560, 3 genes, copy number 5–6: ATP6V0CP3, TBCC, BICRAL.
- chr6:42,984,553–43,161,719, 12 genes, copy number 5: PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2, AL355385.1, PTK7.
- chr6:43,576,185–43,672,600, 5 genes, copy number 5 (within-gene range 1–5): POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9.
- chr8:12,182,096–12,194,133, 1 gene, copy number 6 (within-gene range 2–6): FAM86B1.
- chr8:101,122,145–101,126,158, 1 gene, copy number 5: AP003469.2.
- chr8:102,125,432–102,452,483, 10 genes, copy number 5: MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1, AP002981.1, RNU6ATAC8P, HSPE1P14.
- chr8:102,864,271–103,002,424, 3 genes, copy number 5 (within-gene range 4–5): MAILR, AP003354.1, RPL5P24.
- chr8:103,398,658–103,501,895, 5 genes, copy number 5 (within-gene range 4–5): AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1.
- chr8:108,871,128–109,121,565, 2 genes, copy number 5: AC104248.1, TRHR.
- chr8:109,777,912–109,975,771, 3 genes, copy number 5 (within-gene range 4–5): AC023245.2, AC023245.1, KCNV1.
- chr8:110,105,076–110,105,964, 1 gene, copy number 5: RPSAP48.
- chr8:110,555,408–111,757,710, 12 genes, copy number 5 (within-gene range 4–5): AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7.
- chr8:112,222,928–113,436,939, 4 genes, copy number 5 (within-gene range 4–5): CSMD3, AC024996.1, RPL30P16, MIR2053.
- chr8:113,432,224–113,433,129, 1 gene, copy number 5: AC055788.2.
- chr15:21,293,653–21,946,641, 31 genes, copy number 7–13 (within-gene range 1–13): AC068446.1, AC068446.2, RNU6-1235P, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2.
- chr15:21,990,074–22,095,857, 5 genes, copy number 10 (within-gene range 2–33): AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P.
- chr15:22,070,241–22,095,472, 2 genes, copy number 10 (within-gene range 10–33): OR4M2, OR4N4.
- chr15:22,178,107–22,185,402, 2 genes, copy number 7: IGHV1OR15-3, IGHV4OR15-8.
- chr17:37,977,972–38,257,192, 10 genes, copy number 19: TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA.
- chr17:46,503,946–46,555,650, 2 genes, copy number 7–14 (within-gene range 0–14): RDM1P2, LRRC37A2.
- chr17:46,537,534–46,537,814, 1 gene, copy number 14 (within-gene range 0–14): RN7SL199P.
- chr17:46,590,669–46,757,464, 1 gene, copy number 6 (within-gene range 2–6): NSF.
- chr19:53,666,679–53,675,797, 5 genes, copy number 5: MIR512-1, MIR512-2, MIR1323, MIR498, MIR520E.
- chr19:53,854,581–53,869,107, 1 gene, copy number 5 (within-gene range 2–5): MYADM-AS1.

Autosomal genes at a single copy (total copy number 1): 14,802. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
